FM case AD12449 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/edff41c0-bc08-4666-8131-af021308e5b6

Male, 72.0 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the kidney; primary biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
